Somatic mutation profile of tumor specimen TARGET-10-PARLST-09A (aliquot TARGET-10-PARLST-09A-01D) from TARGET case TARGET-10-PARLST, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.4 years (3,448 days).
Specimen TARGET-10-PARLST-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 02aa4647-d4ef-4792-807f-34ebcfb5cefc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARLST-14A (Bone Marrow Normal), aliquot TARGET-10-PARLST-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2c9747a7-fc48-49ea-850d-96bca465d038

The open-access MAF lists 22 somatic variants for this specimen: 13 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 7, Nonsense Mutation 2, Frame Shift Del 1, 3'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALB | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 74/152 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.109); catalogued as rs150388973, COSV55735680; called by muse, mutect2, varscan2
- CNPY2 | c.62G>A p.R21Q | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as COSV56263816; called by muse, mutect2, varscan2
- CSRNP3 | c.1043A>T p.D348V | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV58774898; called by muse, mutect2, varscan2
- LAMC1 | c.824del p.Y275Lfs*8 | Frame Shift Del (DEL) | VAF 17/54 reads (31%) | catalogued as COSV51132232; called by mutect2, varscan2
- MARK4 | c.2234G>A p.R745H | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as rs1053052298; called by muse, mutect2, varscan2
- PTPRJ | c.817T>C p.Y273H | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV69249690; called by muse, mutect2, varscan2
- USP9Y | c.1633C>T p.R545* | Nonsense Mutation (SNP) | VAF 39/46 reads (85%) | catalogued as COSV59098639; called by muse, mutect2
- DNM1 | c.582C>A p.D194E | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- KIAA0825 | c.1507G>T p.A503S | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PRPS1L1 | c.506C>A p.S169* | Nonsense Mutation (SNP) | VAF 4/29 reads (14%) | called by muse, mutect2
- SCAF8 | c.970C>A p.Q324K | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.054); called by muse, mutect2
- SEC22A | c.169C>A p.H57N | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, mutect2
- ZNF225 | c.2036C>A p.T679K | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.038); called by muse, mutect2
- ANKRD30A | c.2640C>T p.F880= (on ENST00000611781; = p.F824= on NM_052997.2) | Silent (SNP) | VAF 58/186 reads (31%) | catalogued as rs562184589, COSV100654471, COSV64606439; called by muse, mutect2, varscan2
- FIBIN | c.507C>A p.T169= | Silent (SNP) | VAF 27/48 reads (56%) | called by muse, mutect2, varscan2
- FKBP6 | c.549C>T p.R183= | Silent (SNP) | VAF 62/141 reads (44%) | called by muse, mutect2, varscan2
- KMT2A | c.9999C>A p.G3333= | Silent (SNP) | VAF 4/41 reads (10%) | called by muse, mutect2
- LILRB3 | c.1314T>G p.G438= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as rs770310553; called by muse, mutect2
- PEX7 | c.306G>T p.G102= | Silent (SNP) | VAF 22/68 reads (32%) | called by muse, mutect2, varscan2
- TNRC6B | c.1771C>A p.R591= | Silent (SNP) | VAF 26/75 reads (35%) | catalogued as COSV57299596; called by muse, mutect2, varscan2
- FABP5P3 | chr7:152445553 C>T | 3'Flank (SNP) | VAF 10/46 reads (22%) | catalogued as rs1406929756; called by muse, mutect2
- MASTL | c.985-25_985-24insTCT | Intron (INS) | VAF 32/68 reads (47%) | called by mutect2, varscan2
